Somatic mutation profile of tumor specimen TCGA-HT-7479-01A (aliquot TCGA-HT-7479-01A-11D-2024-08) from TCGA case TCGA-HT-7479, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 44.2 years (16,137 days).
Specimen TCGA-HT-7479-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2553a2d6-ae40-4652-8c8b-7c74e355b20b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7479-10A (Blood Derived Normal), aliquot TCGA-HT-7479-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/669acb42-c79c-41e8-825c-52cf9301e717

The open-access MAF lists 22 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 2, Frame Shift Del 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 21/83 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.2055del p.F685Lfs*7 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs772595552, CD051775; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 32/61 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMER3 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.873); catalogued as rs1460586435, COSV58467452; called by muse, mutect2, varscan2
- ASPHD2 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53219799; called by muse, mutect2, varscan2
- CASR | c.2842C>A p.L948M (on ENST00000490131; = p.L1025M on NM_000388.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV56139247; called by muse, mutect2, varscan2
- FAM47A | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); catalogued as COSV60498321; called by muse, mutect2, varscan2
- FRAS1 | c.9379T>C p.S3127P | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53626886; called by muse, mutect2, varscan2
- KRTAP10-8 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as rs782578741, COSV58166285; called by muse, mutect2
- LDLRAP1 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as rs866025690, COSV65473836; called by muse, mutect2
- MOGS | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs554882882, COSV51970574; called by muse, mutect2, varscan2
- OR6K2 | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62743831; called by muse, mutect2, varscan2
- PCDHGB3 | c.566G>T p.S189I | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.689); catalogued as COSV53984873; called by muse, mutect2, varscan2
- PLCH2 | c.683T>G p.F228C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53946165; called by muse, mutect2, varscan2
- PLVAP | c.131T>C p.V44A | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53086364; called by muse, mutect2, varscan2
- TRIM43 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV55528322, COSV99720111; called by muse, mutect2
- ZFP69 | c.1541A>G p.H514R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as rs774466943, COSV65529274; called by muse, mutect2, varscan2
- ZNF300 | c.1708A>T p.I570F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51040374; called by muse, mutect2, varscan2
- ZNF320 | c.1184del p.S395Ifs*86 | Frame Shift Del (DEL) | VAF 32/144 reads (22%) | called by mutect2, pindel, varscan2
- MYT1L | c.1884G>A p.P628= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs745509992, COSV67719011; called by muse, mutect2, varscan2
- TTYH2 | c.495C>T p.G165= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs1036617825, COSV53911850; called by muse, mutect2, varscan2
- PTN | c.-133C>G | 5'UTR (SNP) | VAF 5/61 reads (8%) | catalogued as COSV100780992; called by muse, mutect2
